Gene-level copy-number profile of tumor specimen TCGA-DK-A3IK-01A from TCGA case TCGA-DK-A3IK, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 87.8 years (32,076 days).
Specimen TCGA-DK-A3IK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.e5e19d31-439d-40ce-bdb6-a1beb503e605.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A3IK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 829 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7b5a1718-52ea-4d9d-902b-3e9b1b2521db

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 94; copy number 1: 2,993; copy number 2: 18,853; copy number 3: 25,538; copy number 4: 7,795; copy number 5: 1,797; copy number 6: 598; copy number 7: 768; copy number 8: 453; copy number 9: 242; copy number 10: 265; copy number 11: 106; copy number 12: 104; copy number 13: 126; copy number 15: 37; copy number 17: 1; copy number 18: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A3IK-01A-32D-A219-01): tumor purity 0.5, ploidy 2.97, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 91 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:125,681,177–125,724,217, 2 genes: NUP58P1, TMEM248P1.
- chr4:188,630,924–188,716,725, 3 genes: AC093909.3, AC093909.5, RNU7-192P.
- chr8:150,584–4,994,972, 58 genes (within-gene range 0–3): AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1, AC115485.1, AC023296.1, CSMD1.
- chr8:4,496,392–5,142,707, 7 genes: AC010941.1, AC022068.1, PAICSP4, AC019176.1, AC019176.2, SNORA70, RN7SL318P.
- chr8:6,036,433–6,648,508, 8 genes (within-gene range 0–1): AC079054.1, AC009435.1, AC016065.1, MCPH1, AC016065.2, ANGPT2, AC018398.2, AF287957.1.
- chr8:6,622,124–6,622,220, 1 gene: MIR8055.
- chr9:26,840,685–27,066,134, 7 genes (within-gene range 0–1): CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19.
- chr9:31,253,901–31,381,490, 2 genes: SLC25A6P2, LINC01243.
- chr11:26,285,578–26,331,289, 1 gene: ANO3-AS1.
- chr13:89,833,157–89,837,237, 2 genes: RPL7L1P1, AL355821.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,126 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,174,518–153,923,360, 48 genes, copy number 7 (within-gene range 4–7): AL161636.1, LELP1, PRR9, AL161636.2, LORICRIN, PGLYRP3, PGLYRP4, RNU6-160P, S100A9, S100A12, LAPTM4BP1, S100A8, S100A15A, S100A7A, S100A7P1, S100A7L2, S100A7, RN7SL44P, BX470102.1, S100A6, S100A5, S100A4, S100A3, S100A2, BX470102.2, S100A16, S100A14, S100A13, AL162258.1, S100A1, AL162258.2, CHTOP, SNAPIN, ILF2, NPR1, MIR8083, RN7SL372P, GEMIN2P1, Y_RNA, INTS3, AL513523.4, AL513523.3, SLC27A3, Y_RNA, GATAD2B, AL513523.2, AL513523.1, AL831737.1.
- chr1:157,232,231–157,310,655, 3 genes, copy number 8: AL138900.1, LINC02772, AL138900.2.
- chr1:160,062,461–193,254,815, 652 genes, copy number 8–18 (broad region; genes not listed).
- chr2:22,377,594–22,548,800, 2 genes, copy number 8–9 (within-gene range 6–9): LINC01830, LINC01884.
- chr3:18,445,024–18,920,401, 1 gene, copy number 7 (within-gene range 3–7): SATB1-AS1.
- chr3:187,423,315–187,449,450, 2 genes, copy number 10: AC068299.1, LINC02041.
- chr4:10,199,823–10,295,579, 8 genes, copy number 9: AC006499.1, AC006499.8, RAF1P1, AC006499.4, AC006499.2, AC006499.3, AC006499.5, AC006499.7.
- chr4:84,233,657–85,246,912, 14 genes, copy number 7: RNU6-774P, AC025538.1, AC104063.1, NKX6-1, RPL3P13, CDS1, WDFY3, RN7SL552P, WDFY3-AS1, RNU6-469P, WDFY3-AS2, AC108021.1, RN7SKP48, AC097488.1.
- chr5:155,397,291–155,493,598, 2 genes, copy number 8: AC010591.1, AC008725.1.
- chr7:7,906,519–7,950,709, 3 genes, copy number 7: RNU6-534P, CCNB2P1, AC006042.3.
- chr7:40,135,005–40,860,763, 1 gene, copy number 11 (within-gene range 5–11): SUGCT.
- chr7:40,538,127–41,133,507, 4 genes, copy number 11: SUGCT-AS1, AC005160.1, LINC01450, LINC01449.
- chr8:42,537,529–51,321,118, 119 genes, copy number 7 (broad region; genes not listed).
- chr8:51,435,602–51,436,509, 1 gene, copy number 7: BRIX1P1.
- chr8:90,198,389–121,994,185, 441 genes, copy number 7–12 (within-gene range 3–18) (broad region; genes not listed).
- chr8:121,954,640–139,508,971, 235 genes, copy number 7–11 (within-gene range 7–17) (broad region; genes not listed).
- chr11:81,552,226–81,556,425, 2 genes, copy number 8: MTND4LP18, MTND6P25.
- chr14:53,169,010–53,917,753, 6 genes, copy number 7 (within-gene range 4–7): AL365295.1, AL365295.2, AL163953.1, RPS3AP46, LINC02331, AL138479.1.
- chr15:25,135,642–25,159,279, 2 genes, copy number 7: PWAR1, SNORD115.
- chr16:27,133,483–33,622,547, 398 genes, copy number 7 (broad region; genes not listed).
- chr17:37,375,985–38,704,747, 38 genes, copy number 7: C17orf78, AC243654.3, TADA2A, AC243654.1, AC243654.2, DUSP14, SYNRG, AC243585.2, DDX52, MIR378J, AC243571.2, AC243585.1, HNF1B, AC243571.1, YWHAEP7, RNU6-489P, TBC1D3K, 5S_rRNA, TBC1D3L, TBC1D3D, TBC1D3C, AC233968.1, Y_RNA, TBC1D3E, RNA5SP526, TBC1D3, NPEPPSP1, Y_RNA, MRPL45, GPR179, SOCS7, ARHGAP23, AC244153.1, SRCIN1, AC006449.1, EPOP, MIR4734, AC006449.6.
- chr19:39,584,042–39,738,029, 16 genes, copy number 8: AC011500.1, RPS29P24, RPS29P25, RPS29P26, LGALS13, AC005176.2, AC005176.1, RPS29P30, LGALS16, LGALS17A, AC005515.1, AC093063.1, RPS29P27, LGALS14, AC006133.1, CLC.
- chr21:18,022,370–18,114,904, 1 gene, copy number 7 (within-gene range 3–7): AF130417.1.
- chr22:19,257,520–21,517,533, 125 genes, copy number 10 (broad region; genes not listed).
- chr22:27,044,001–27,061,247, 2 genes, copy number 10 (within-gene range 3–10): AL008638.4, AL008638.2.

Autosomal genes at a single copy (total copy number 1): 2,982. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
